CCDI case PBBWAR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/146db13e-7f89-4f6e-a7f6-08663054fa3b

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.7 years (2,097 days).

Biospecimens (3 samples)
- Sample 0DIPKS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIPL9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DIPLS: Tissue type: Tumor; Specimen type: Solid Tissue.
